Somatic mutation profile of tumor specimen TCGA-EK-A2PG-01A (aliquot TCGA-EK-A2PG-01A-11D-A18J-09) from TCGA case TCGA-EK-A2PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 89.0 years (32,500 days).
Specimen TCGA-EK-A2PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daa2359b-2a60-4791-87c3-9fd13e29eb97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2PG-10A (Blood Derived Normal), aliquot TCGA-EK-A2PG-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9472bc32-93f1-41dd-91f9-f3cf96765a4a

The open-access MAF lists 609 somatic variants for this specimen: 435 protein-altering or splice-affecting, 158 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 396, Silent 158, Nonsense Mutation 26, Intron 8, Splice Region 5, Splice Site 5, 5'UTR 3, RNA 2, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV55598856, COSV55601707; called by muse, mutect2, varscan2
- ABCB4 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55940814; called by muse, mutect2
- ABCC4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769663620, COSV65317475; called by muse, mutect2, varscan2
- ABHD13 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV65535064; called by muse, mutect2, varscan2
- ACAT2 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV65454874; called by muse, mutect2, varscan2
- ACOT2 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53151394; called by muse, mutect2, varscan2
- ACSF3 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58081228; called by muse, mutect2, varscan2
- ACTG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59511786; called by muse, mutect2, varscan2
- ACTG1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV59511602; called by muse, mutect2, varscan2
- ACTG1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV59509957, COSV59511807; called by muse, mutect2, varscan2
- ADCY2 | c.2743C>A p.L915I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57875685; called by muse, mutect2
- ADCY4 | c.2521C>T p.L841F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60257109, COSV60257941; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs745709763, COSV58446086; called by muse, mutect2, varscan2
- ADGRB2 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs780752747, COSV57077978; called by mutect2, varscan2
- ADGRG4 | c.5813C>T p.S1938L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.161); catalogued as COSV54964800; called by muse, mutect2, varscan2
- ADGRV1 | c.15460G>C p.E5154Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV67993691; called by muse, mutect2, varscan2
- AGER | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV61248559; called by muse, mutect2, varscan2
- AKAP9 | c.9886G>A p.E3296K (on ENST00000359028; = p.E3272K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs771303714, COSV62355919; called by muse, mutect2, varscan2
- AL592490.1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV69427568; called by muse, mutect2
- ALG13 | c.3254G>T p.C1085F | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV52644085; called by muse, mutect2, varscan2
- AMPD2 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56650235; called by muse, mutect2
- ANK1 | c.4832G>A p.R1611Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs538742550, COSV55876571; called by muse, mutect2, varscan2
- ANXA3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV53716547; called by muse, mutect2, varscan2
- AOC3 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53828457; called by muse, mutect2, varscan2
- AP5Z1 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as rs1233553130, COSV62243448; called by muse, mutect2, varscan2
- APMAP | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV54176483, COSV54176642; called by muse, mutect2
- ARHGEF9 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99491780; called by muse, mutect2
- ARL14EP | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247161671, COSV56343458; called by muse, mutect2, varscan2
- ARNTL | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62988437; called by muse, mutect2, varscan2
- ASAP3 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60877471; called by muse, mutect2, varscan2
- ASPH | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs140478604; called by muse, mutect2, varscan2
- ATXN3L | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV66076169; called by muse, mutect2
- AVPR2 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686826; called by muse, mutect2, varscan2
- B3GNT9 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54626374; called by muse, mutect2, varscan2
- BAG2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV58099128; called by muse, mutect2, varscan2
- BAIAP3 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60983336; called by muse, mutect2, varscan2
- BBS5 | c.387-1G>A p.X129_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | catalogued as rs1312890801, COSV54754052; called by muse, mutect2, varscan2
- BCL9L | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.655); catalogued as COSV52688465, COSV99420599; called by muse, mutect2, varscan2
- BEND7 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61990948; called by muse, mutect2, varscan2
- BHLHA15 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV52002611; called by muse, mutect2, varscan2
- BRCA1 | c.5231G>A p.R1744K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1567764460, CD1111490, COSV58797660; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- BRDT | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148311319; called by muse, mutect2, varscan2
- BRWD1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV60901624; called by muse, mutect2, varscan2
- BRWD3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1239592366, COSV64752669; called by muse, mutect2, varscan2
- C10orf90 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as rs1327980423, COSV52956752, COSV52962577; called by muse, mutect2, varscan2
- C17orf75 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as COSV56753953; called by muse, mutect2, varscan2
- C4BPA | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs764249458, COSV65537363; called by muse, mutect2, varscan2
- C4orf19 | c.470T>A p.V157D | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV52650167; called by muse, mutect2, varscan2
- CA10 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368512398; called by muse, mutect2, varscan2
- CA14 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV99354378; called by muse, mutect2, varscan2
- CA14 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV52530392; called by muse, mutect2, varscan2
- CAD | c.4202G>C p.G1401A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV53024189, COSV53031035; called by muse, mutect2, varscan2
- CADM4 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV55928478; called by muse, mutect2, varscan2
- CAMSAP1 | c.4007G>A p.R1336Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1394273139, COSV56723396; called by muse, mutect2, varscan2
- CARD11 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs560138497, COSV62756781; called by muse, mutect2, varscan2
- CASP6 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV54461788; called by muse, mutect2, varscan2
- CASQ1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.672); catalogued as rs756999370, COSV63623243; called by muse, mutect2, varscan2
- CASS4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64388109; called by muse, mutect2, varscan2
- CCDC17 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143765805; called by muse, mutect2, varscan2
- CCDC38 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV60184551; called by muse, mutect2, varscan2
- CCDC74B | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV60103473; called by muse, mutect2, varscan2
- CCM2L | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52952186; called by muse, mutect2, varscan2
- CCT8 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1383131908, COSV54505858, COSV99726080; called by muse, mutect2, varscan2
- CCZ1 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100382813; called by muse, mutect2, varscan2
- CD163 | c.1547G>A p.C516Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136477; called by muse, mutect2, varscan2
- CDC27 | c.1884C>G p.I628M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs776145016, COSV50382612, COSV50657329; called by muse, mutect2, varscan2
- CDC27 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV50657472; called by muse, mutect2, varscan2
- CDC42BPB | c.2158C>A p.H720N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV63476486; called by muse, mutect2
- CDCA4 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV60316090; called by muse, mutect2, varscan2
- CDCA7L | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV60976154; called by muse, mutect2, varscan2
- CDH13 | c.1769C>A p.A590D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99225954; called by muse, mutect2, varscan2
- CDK17 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV54132772; called by mutect2, varscan2
- CELSR2 | c.8052G>A p.L2684= | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as COSV54778337; called by muse, mutect2, varscan2
- CELSR2 | c.8227G>A p.E2743K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV54778352; called by muse, mutect2, varscan2
- CEP350 | c.4747G>A p.D1583N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1014505972, COSV100855444, COSV62608687; called by muse, mutect2, varscan2
- CERK | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53452932; called by muse, mutect2, varscan2
- CFAP70 | c.1981-1G>C p.X661_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV60282341; called by muse, mutect2, varscan2
- CFHR4 | c.1355-2A>C p.X452_splice (on ENST00000367416 / NM_001201551.2; = p.X206_splice on NM_006684.5) | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52234694; called by mutect2, varscan2
- CFHR5 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as rs771400518, COSV56827190; called by muse, mutect2, varscan2
- CHD4 | c.2217G>C p.E739D (on ENST00000357008 / NM_001363606.2; = p.E752D on NM_001273.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58909051; called by muse, mutect2, varscan2
- CHRNB1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201453432; called by muse, mutect2, varscan2
- CHRNE | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as rs1056080125, COSV53419663; called by muse, mutect2, varscan2
- CKM | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.442); catalogued as COSV55534859, COSV99675525; called by muse, mutect2, varscan2
- CLC | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs867849565, COSV55686321; called by muse, varscan2
- CLDN22 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV60109837; called by muse, mutect2, varscan2
- CLK1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV58435490; called by muse, mutect2, varscan2
- CLSTN3 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as rs182094956, COSV56935635; called by muse, mutect2, varscan2
- CNTN3 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55182166; called by muse, mutect2, varscan2
- COL5A2 | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV66413028; called by muse, mutect2, varscan2
- CR1L | c.1041G>A p.V347= | Splice Region (SNP) | VAF 48/205 reads (23%) | catalogued as rs747646746, COSV54322984, COSV54330672; called by muse, mutect2, varscan2
- CREB3L2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57799220; called by muse, mutect2, varscan2
- CROCC | c.3169G>C p.E1057Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65014430; called by muse, mutect2, varscan2
- CSE1L | c.1122G>C p.L374F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53704549; called by muse, mutect2, varscan2
- CST2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100491224; called by muse, mutect2, varscan2
- CYP4A22 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.103); catalogued as COSV53742127; called by muse, mutect2, varscan2
- CYP8B1 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV104412253, COSV60227464; called by mutect2, varscan2
- CYRIA | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV62866798; called by muse, mutect2, varscan2
- DAPK3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV56664496; called by muse, varscan2
- DDO | c.719G>T p.G240V (on ENST00000368924 / NM_001368172.1; = p.G181V on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64470520; called by muse, mutect2, varscan2
- DDR2 | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100906637, COSV63372557; called by muse, mutect2, varscan2
- DDX41 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV57905428; called by muse, mutect2, varscan2
- DENND2B | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV58202022, COSV58207160; called by muse, mutect2, varscan2
- DENND5B | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV60907273; called by muse, mutect2, varscan2
- DHX9 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62361080; called by muse, mutect2, varscan2
- DIAPH2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61288826; called by muse, mutect2, varscan2
- DIAPH2 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.865); catalogued as COSV61284532; called by muse, mutect2, varscan2
- DMGDH | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV54867918; called by muse, mutect2, varscan2
- DNA2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV64429893; called by muse, mutect2
- DNAAF2 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs137853191, CM086380, COSV53571524; called by muse, mutect2, varscan2
- DNAAF3 | c.107C>T p.S36F (on ENST00000524407 / NM_001256715.2; = p.S83F on NM_178837.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV66992909; called by muse, mutect2, varscan2
- DNAH11 | c.9025G>T p.D3009Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60976140; called by muse, mutect2, varscan2
- DNAJC15 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs756868611, COSV101004960, COSV64871757; called by muse, mutect2, varscan2
- DNAL1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60728573; called by muse, varscan2
- DPP8 | c.1879C>T p.L627F (on ENST00000341861 / NM_001320875.2; = p.L611F on NM_017743.6) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.157); catalogued as COSV55679094, COSV55682554; called by muse, mutect2, varscan2
- DPYSL3 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs751361322, COSV58330391; called by mutect2, varscan2
- DST | c.20278A>G p.S6760G (on ENST00000361203 / NM_001374722.1; = p.S4457G on NM_015548.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.129); catalogued as COSV55035411; called by muse, mutect2
- DST | c.16757C>T p.A5586V (on ENST00000361203 / NM_001374722.1; = p.A3283V on NM_015548.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV55013340; called by muse, mutect2
- DYNC1LI2 | c.180C>T p.F60= | Splice Region (SNP) | VAF 17/91 reads (19%) | catalogued as COSV50755999; called by muse, mutect2, varscan2
- DZIP1 | c.2578G>A p.D860N (on ENST00000347108; = p.D841N on NM_014934.5) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54825883; called by muse, mutect2, varscan2
- E2F2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765421608, COSV62276733; called by muse, mutect2, varscan2
- E2F8 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV51461557, COSV51465756; called by muse, mutect2, varscan2
- EGR1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs1302695548, COSV53519424; called by muse, mutect2, varscan2
- EGR1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53521200; called by muse, mutect2, varscan2
- EIF2AK3 | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.902); catalogued as COSV57551308; called by muse, mutect2, varscan2
- ELMO1 | c.1214G>C p.R405P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100164725, COSV60320825; called by muse, mutect2, varscan2
- ELOA | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV69311189; called by muse, mutect2
- EP400 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV57784205; called by muse, mutect2, varscan2
- EPB41L3 | c.2022G>C p.L674F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs781737635, COSV59465257; called by muse, mutect2, varscan2
- EPHB6 | c.101-1G>C p.X34_splice | Splice Site (SNP) | VAF 14/92 reads (15%) | catalogued as COSV67420504; called by muse, mutect2, varscan2
- ERCC6 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs150065567; called by muse, mutect2, varscan2
- ERLIN1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV64941287; called by muse, mutect2, varscan2
- ESPN | c.2295G>C p.K765N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64704519, COSV64705304; called by muse, mutect2, varscan2
- EXOC6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53327538; called by muse, varscan2
- EXOC7 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV58744405; called by muse, mutect2, varscan2
- EYA1 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs751887655, COSV100379378, COSV100380306; called by muse, mutect2, varscan2
- FAH | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV55723347; called by muse, mutect2, varscan2
- FAM171A1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65319307; called by muse, mutect2, varscan2
- FAM76B | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV57690118, COSV57691033; called by muse, mutect2, varscan2
- FAT1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs773408982, COSV71675627; called by muse, mutect2, varscan2
- FAT2 | c.8960C>G p.S2987C | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55827784; called by muse, mutect2, varscan2
- FGFR4 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV52808839; called by muse, mutect2, varscan2
- FLG | c.8890G>A p.A2964T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV64247352; called by muse, mutect2, varscan2
- FLNC | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs753022721, COSV57962280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066726; called by muse, mutect2, varscan2
- FOLR1 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747612073, COSV56617035; called by muse, mutect2, varscan2
- FRY | c.5452C>G p.Q1818E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.18); catalogued as rs757501056, COSV100968957, COSV66577743; called by mutect2, varscan2
- FRYL | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51959293; called by muse, mutect2, varscan2
- GAA | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs762439362, COSV56411234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAREM1 | c.1325C>G p.S442* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52514992; called by muse, mutect2
- GATC | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57571045; called by muse, mutect2, varscan2
- GGT7 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60542252; called by muse, mutect2, varscan2
- GIP | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV62467679; called by muse, mutect2, varscan2
- GLDN | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59092022; called by muse, mutect2, varscan2
- GLRA4 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV60328278; called by muse, mutect2, varscan2
- GMPS | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879113982, COSV55811444; called by muse, mutect2, varscan2
- GPC1 | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99882884; called by muse, mutect2, varscan2
- GPC3 | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV63670724; called by muse, mutect2, varscan2
- GPRASP1 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64356335; called by muse, mutect2, varscan2
- GPRC5B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs148205185; called by muse, mutect2, varscan2
- GPRIN1 | c.1556G>C p.G519A | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56144063; called by muse, mutect2, varscan2
- GSPT2 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61214877; called by muse, mutect2, varscan2
- H1-8 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV60718804; called by muse, mutect2, varscan2
- HAUS2 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV53000998, COSV99535603; called by muse, mutect2, varscan2
- HDAC3 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV59497313; called by muse, mutect2, varscan2
- HDAC9 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV67783480; called by mutect2, varscan2
- HELZ2 | c.1985C>T p.S662F (on ENST00000467148 / NM_001037335.2; = p.S93F on NM_033405.3) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64410377; called by muse, mutect2, varscan2
- HERC1 | c.13225G>A p.D4409N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV71249821; called by muse, mutect2, varscan2
- HERC5 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.071); catalogued as COSV52043831; called by muse, mutect2, varscan2
- HIPK4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99396670; called by muse, mutect2, varscan2
- HP | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV63326371; called by muse, mutect2, varscan2
- HPS4 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV61105192; called by muse, mutect2, varscan2
- HSD3B2 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs587631086, COSV65593228, COSV65593903; called by muse, mutect2, varscan2
- HSPA8 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV57085946; called by muse, mutect2, varscan2
- HTR3E | c.1076G>A p.R359K (on ENST00000415389 / NM_001256613.1; = p.R374K on NM_182589.2) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58946415; called by muse, mutect2, varscan2
- HYDIN | c.9832G>A p.G3278R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564737189, COSV66886017; called by muse, mutect2, varscan2
- HYDIN | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.831); catalogued as COSV66886030; called by muse, mutect2, varscan2
- ICAM3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV50329919; called by muse, mutect2, varscan2
- IFT57 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV52711474; called by muse, mutect2, varscan2
- IL6R | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV59818860; called by muse, varscan2
- IL6R | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752283963, COSV59817418, COSV59818873; called by muse, varscan2
- IMMT | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV54489568; called by muse, mutect2, varscan2
- INPP5B | c.1408C>T p.H470Y (on ENST00000373023; = p.H390Y on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1026401340, COSV100886477; called by muse, mutect2, varscan2
- INTU | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as rs955453867, COSV58874157; called by muse, mutect2, varscan2
- IQGAP1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV51590289; called by muse, varscan2
- IQGAP2 | c.2622G>C p.L874F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1038236033, COSV57180354; called by muse, mutect2, varscan2
- ITGAM | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV54941533; called by muse, mutect2, varscan2
- ITSN1 | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66085396; called by muse, mutect2, varscan2
- IWS1 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV54871239; called by mutect2, varscan2
- JAK2 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 82/85 reads (96%) | catalogued as COSV67661762; called by muse, mutect2, varscan2
- JUND | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53254893; called by muse, mutect2, varscan2
- KANSL1 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV52273132; called by muse, mutect2, varscan2
- KANSL1L | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762505094, COSV55993885; called by muse, mutect2, varscan2
- KATNB1 | c.1176C>T p.I392= | Splice Region (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101109182; called by muse, mutect2, varscan2
- KCTD1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); catalogued as COSV58690226; called by muse, mutect2, varscan2
- KCTD2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as rs202181641, COSV100483315; called by muse, mutect2, varscan2
- KCTD4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.277); catalogued as rs562563207, COSV61242345; called by muse, mutect2, varscan2
- KDM5A | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66995717; called by muse, mutect2, varscan2
- KDSR | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV58507941; called by muse, mutect2, varscan2
- KIF4A | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV65545311; called by muse, mutect2, varscan2
- KIF5B | c.163A>C p.S55R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs775994666, COSV56655684; called by muse, mutect2, varscan2
- KIFAP3 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1049587093, COSV63036595; called by muse, mutect2, varscan2
- KIR3DL2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs141407209; called by muse, mutect2, varscan2
- KLKB1 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV52998659; called by muse, mutect2, varscan2
- KMT2B | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52892192; called by muse, mutect2, varscan2
- KMT2C | c.3216G>C p.Q1072H | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51491224; called by muse, mutect2, varscan2
- KMT5B | c.1362G>C p.L454F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV58569215; called by muse, mutect2, varscan2
- KNTC1 | c.2786G>C p.R929T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61083409; called by muse, mutect2, varscan2
- KRT4 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs950673957, COSV53409370; called by muse, mutect2, varscan2
- KRTAP10-2 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV59961962; called by muse, mutect2, varscan2
- KRTAP4-12 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1373505971, COSV67458223; called by muse, mutect2, varscan2
- LAMB3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61919096; called by muse, mutect2, varscan2
- LIG1 | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54395432; called by muse, mutect2, varscan2
- LMAN1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV51828813; called by muse, mutect2, varscan2
- LMAN1L | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763491666, COSV59003302; called by mutect2, varscan2
- LMO7 | c.2539C>T p.Q847* (on ENST00000357063; = p.Q528* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV58546086; called by muse, mutect2, varscan2
- LONRF2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs1176119486, COSV66539664; called by muse, mutect2, varscan2
- LPA | c.90T>G p.H30Q | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.977); catalogued as COSV60309751; called by muse, mutect2, varscan2
- LRIG3 | c.3274C>T p.Q1092* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57869028; called by muse, mutect2, varscan2
- LRP2 | c.6642G>T p.K2214N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55552681; called by muse, mutect2, varscan2
- LRPPRC | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV53242364; called by muse, varscan2
- LRPPRC | c.1656G>C p.M552I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV53233950; called by muse, mutect2, varscan2
- LRRC43 | c.1235C>G p.S412W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV60292809; called by muse, mutect2, varscan2
- LRRC75A | c.628G>T p.G210C (on ENST00000470794 / NM_001113567.3; = p.G171V on NM_207387.4) | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV63359231; called by muse, mutect2, varscan2
- LRSAM1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs767351229, COSV55938308; called by muse, mutect2, varscan2
- LTBP3 | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54215314; called by muse, mutect2, varscan2
- MAGEA3 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV64756470; called by muse, mutect2, varscan2
- MAGEB10 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63312496; called by muse, mutect2, varscan2
- MAGI2 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.398); catalogued as COSV62691724; called by muse, mutect2, varscan2
- MAGT1 | c.923G>C p.G308A (on ENST00000618282 / NM_001367916.1; = p.G340A on NM_032121.5) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV100800214; called by muse, mutect2
- MAP2 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs770296783, COSV52305003; called by muse, mutect2, varscan2
- MAP4K1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1344372115, COSV67712719; called by mutect2, varscan2
- MAPK10 | c.1006C>G p.Q336E (on ENST00000359221 / NM_001351625.2; = p.Q374E on NM_002753.5) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100174462; called by muse, mutect2
- MARS2 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV56572234; called by muse, mutect2, varscan2
- MCM6 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as COSV51465898, COSV51468760; called by muse, mutect2, varscan2
- MIER1 | c.499G>A p.E167K (on ENST00000355356 / NM_001077701.3; = p.E184K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV62531822; called by mutect2, varscan2
- MIS18BP1 | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV60371215, COSV60373092; called by muse, mutect2, varscan2
- MKI67 | c.3550G>T p.E1184* | Nonsense Mutation (SNP) | VAF 31/184 reads (17%) | catalogued as COSV64074965, COSV64076402; called by muse, mutect2, varscan2
- MLLT10 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV56993311; called by muse, mutect2, varscan2
- MMS19 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59137127; called by muse, mutect2, varscan2
- MTUS2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV70920711; called by muse, mutect2, varscan2
- MYCBP2 | c.13598G>C p.R4533T (on ENST00000357337; = p.R4571T on NM_015057.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs1428877966, COSV62035821; called by muse, mutect2, varscan2
- MYO16 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as COSV51814391; called by muse, mutect2, varscan2
- MYO18A | c.3760G>T p.E1254* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV62872301; called by muse, mutect2, varscan2
- MYO5A | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV62560251, COSV62563848; called by mutect2, varscan2
- MYO9A | c.7153G>T p.E2385* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61856421; called by muse, mutect2, varscan2
- MYSM1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV71763225; called by muse, mutect2, varscan2
- NACC1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52835705; called by muse, mutect2, varscan2
- NBEA | c.4012C>G p.P1338A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV59815806; called by muse, mutect2, varscan2
- NBPF20 | c.16646G>C p.R5549T (on ENST00000369373; = p.R5110T on NM_001278267.1) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); catalogued as COSV65011388; called by muse, varscan2
- NCSTN | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54191047; called by muse, mutect2, varscan2
- NEB | c.7053G>C p.E2351D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51452404, COSV51457827; called by muse, mutect2, varscan2
- NFASC | c.3098T>C p.F1033S | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.283); catalogued as COSV58377329; called by muse, mutect2, varscan2
- NHS | c.4185C>G p.I1395M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV66281076; called by muse, mutect2, varscan2
- NIPBL | c.703C>G p.H235D | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV56962847; called by muse, mutect2, varscan2
- NIPSNAP1 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV53343823; called by muse, mutect2, varscan2
- NKAP | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57631113; called by muse, mutect2, varscan2
- NLGN1 | c.1314C>G p.F438L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100849401, COSV64344596; called by muse, mutect2, varscan2
- NMD3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63619511, COSV99053240; called by muse, mutect2, varscan2
- NOL7 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as rs201177610, COSV100702828; called by muse, mutect2, varscan2
- NPHP1 | c.2032G>C p.E678Q (on ENST00000393272 / NM_207181.4; = p.E679Q on NM_000272.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1418617951, COSV57211074; called by muse, mutect2, varscan2
- NPHP3 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as rs1448348187, COSV58632878; called by muse, mutect2, varscan2
- NPY5R | c.1091G>C p.R364P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768685790, COSV58452026, COSV58453583; called by muse, mutect2
- NRBP1 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV51994998; called by muse, mutect2, varscan2
- NRXN3 | c.332A>T p.D111V (on ENST00000557594 / NM_001272020.2; = p.D743V on NM_004796.6) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55349116; called by muse, mutect2, varscan2
- NSD1 | c.3522G>A p.M1174I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV61783162; called by muse, mutect2, varscan2
- NSUN7 | c.1051C>A p.H351N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57275959; called by muse, mutect2, varscan2
- OAS2 | c.2150G>C p.R717T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as COSV60804189; called by muse, mutect2, varscan2
- OBI1 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV56147012; called by muse, mutect2, varscan2
- OBSCN | c.12185C>T p.S4062F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV52818095; called by muse, mutect2, varscan2
- OR10A5 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV55055438; called by muse, mutect2, varscan2
- OR2AK2 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV63559510; called by muse, mutect2, varscan2
- OR2M5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs147580819; called by muse, mutect2, varscan2
- OSR2 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 103/144 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV52558532; called by muse, mutect2, varscan2
- P2RX2 | c.717C>G p.F239L (on ENST00000343948 / NM_170683.4; = p.F167L on NM_012226.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV57688606; called by muse, varscan2
- PABPC5 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57042854, COSV57043672; called by muse, mutect2, varscan2
- PALM | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1162854586, COSV52770510; called by muse, mutect2, varscan2
- PAMR1 | c.1933G>A p.D645N (on ENST00000619888 / NM_001001991.3; = p.D662N on NM_015430.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV53515831; called by muse, mutect2, varscan2
- PARP9 | c.1415A>T p.D472V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64451655; called by muse, mutect2, varscan2
- PCDHA5 | c.1863C>G p.F621L | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV65356802; called by muse, mutect2, varscan2
- PCDHB15 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782788911, COSV50886810; called by muse, mutect2, varscan2
- PCDHGB6 | c.1705C>G p.P569A | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV54015374; called by muse, mutect2, varscan2
- PCSK7 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV58009148; called by muse, mutect2, varscan2
- PDE1A | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV59534108; called by muse, mutect2, varscan2
- PDE4A | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.273); catalogued as COSV53361213; called by muse, mutect2, varscan2
- PEAK1 | c.3421G>C p.D1141H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56941961; called by muse, mutect2, varscan2
- PIGA | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61237682; called by muse, mutect2, varscan2
- PIK3R6 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0.165); catalogued as COSV61005303; called by muse, varscan2
- PITHD1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs1416333881, COSV55755699; called by muse, mutect2, varscan2
- PLA1A | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs527683151, COSV56333478, COSV99845935; called by muse, mutect2, varscan2
- PLA2G2C | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.398); catalogued as rs1232765532, COSV56124980; called by muse, mutect2, varscan2
- PLA2G2D | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs575656652, COSV64281608, COSV64282061; called by muse, mutect2, varscan2
- PLA2G4F | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV51829083; called by muse, mutect2, varscan2
- PLA2G4F | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.441); catalogued as COSV51829090; called by muse, mutect2, varscan2
- PLCH1 | c.190+1G>C p.X64_splice (on ENST00000340059 / NM_001130960.2; = p.X76_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/116 reads (15%) | catalogued as COSV58208451; called by muse, mutect2, varscan2
- PLCZ1 | c.643C>A p.H215N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856355; called by muse, mutect2, varscan2
- PLIN5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV67850989; called by muse, mutect2, varscan2
- POLQ | c.3692C>G p.S1231* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV51759577; called by muse, mutect2, varscan2
- POLQ | c.1249C>G p.H417D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51745820, COSV51759585; called by muse, mutect2, varscan2
- POLR1B | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502717; called by muse, mutect2, varscan2
- PPFIBP1 | c.833C>T p.S278F (on ENST00000318304 / NM_177444.3; = p.S247F on NM_003622.4) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV57297659; called by muse, mutect2, varscan2
- PPP1R17 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59612320; called by muse, mutect2, varscan2
- PRAMEF14 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV58050198; called by muse, mutect2, varscan2
- PRAMEF2 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as rs775162695, COSV53578529; called by muse, mutect2, varscan2
- PRB3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV54392592, COSV54392915; called by muse, mutect2, varscan2
- PREP | c.1209C>G p.F403L (on ENST00000369110; = p.F469L on NM_002726.5) | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64869520, COSV64871731; called by muse, mutect2, varscan2
- PRPS1L1 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV101552932; called by muse, mutect2, varscan2
- PRTG | c.3127C>G p.P1043A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66840196; called by muse, mutect2, varscan2
- PRUNE2 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV65046632; called by muse, mutect2, varscan2
- PSMC2 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV50793648; called by muse, mutect2, varscan2
- PSMD2 | c.671A>T p.N224I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV59531201; called by muse, mutect2
- PSMD9 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55840546; called by muse, mutect2, varscan2
- PTGDR | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60094658, COSV60094875; called by muse, mutect2, varscan2
- PTK7 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV57851043; called by muse, mutect2, varscan2
- PTPRT | c.4072C>T p.R1358* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV61966484, COSV62022626; called by muse, mutect2, varscan2
- PTPRT | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62011971; called by muse, mutect2, varscan2
- PUF60 | c.567G>C p.Q189H (on ENST00000526683 / NM_001362896.2; = p.Q172H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV57592474; called by muse, mutect2, varscan2
- RAB11FIP2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV62925955; called by muse, mutect2, varscan2
- RAD54L2 | c.3522G>C p.E1174D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV56581035, COSV99620813; called by muse, mutect2, varscan2
- RADIL | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs764623431, COSV68203178; called by muse, mutect2, varscan2
- RALY | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55783520; called by muse, mutect2, varscan2
- RASEF | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs754663384, COSV64588402; called by muse, mutect2, varscan2
- RCSD1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63260713; called by muse, mutect2, varscan2
- RECQL4 | c.1664C>T p.S555L | Missense Mutation (SNP) | VAF 118/166 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs755425093, COSV52881456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REM2 | c.427C>G p.H143D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV57465921, COSV57465980; called by muse, mutect2, varscan2
- REXO5 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV54473764, COSV54474306; called by muse, mutect2, varscan2
- RHBDL2 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56709643; called by muse, mutect2, varscan2
- RIMS2 | c.174C>A p.L58= | Splice Region (SNP) | VAF 33/48 reads (69%) | catalogued as COSV68497466; called by muse, mutect2, varscan2
- RND1 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59045981; called by muse, mutect2, varscan2
- RND2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56816670, COSV56816781; called by muse, mutect2, varscan2
- RNF212 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61365736; called by muse, mutect2, varscan2
- ROBO1 | c.4163C>G p.S1388C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV71397817, COSV71398553; called by muse, mutect2, varscan2
- RPAP2 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV72101650; called by muse, mutect2, varscan2
- RPGRIP1L | c.1855G>C p.E619Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV50914832; called by muse, mutect2, varscan2
- RPH3AL | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs867104080, COSV58746747; called by muse, mutect2, varscan2
- RPS6KA3 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101084459, COSV65389190; called by muse, mutect2, varscan2
- RPS6KA6 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV53125552; called by muse, mutect2, varscan2
- RRBP1 | c.3946G>C p.E1316Q (on ENST00000377813 / NM_001365613.2; = p.E883Q on NM_004587.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV55707014; called by muse, mutect2, varscan2
- RSPH10B | c.1588C>G p.P530A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs763653434, COSV100521296; called by mutect2, varscan2
- RTEL1 | c.1716C>A p.F572L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV58900333; called by muse, mutect2, varscan2
- RXFP1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57055210; called by muse, mutect2, varscan2
- RYR3 | c.5215G>C p.D1739H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV101212760, COSV66807016; called by muse, mutect2
- SCN9A | c.5770G>A p.D1924N (on ENST00000303354; = p.D1913N on NM_002977.3) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57621458; called by muse, mutect2, varscan2
- SEC31A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58872605, COSV58879764; called by muse, mutect2
- SEC31B | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs543510700, COSV100947314, COSV100947518; called by mutect2, varscan2
- SEMA4B | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60175548; called by muse, varscan2
- SENP7 | c.3143G>A p.S1048N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV58617343; called by muse, mutect2, varscan2
- SETD2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV57437029, COSV57442585, COSV57443759; called by muse, mutect2, varscan2
- SETD5 | c.2827G>C p.D943H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56716383; called by muse, mutect2, varscan2
- SGSM3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs547805871, COSV50654675; called by muse, mutect2, varscan2
- SHROOM3 | c.1702G>C p.D568H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV56030313, COSV56037865; called by muse, mutect2, varscan2
- SIGLEC1 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs200143991; called by mutect2, varscan2
- SIMC1 | c.2503G>A p.E835K (on ENST00000443967 / NM_001308196.1; = p.E420K on NM_198567.5) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53799916; called by muse, mutect2, varscan2
- SIRT7 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV58712459; called by muse, mutect2, varscan2
- SLC27A3 | c.1727C>A p.S576Y (on ENST00000271857; = p.S448Y on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55165029, COSV55165369; called by muse, mutect2, varscan2
- SLC28A1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as COSV54484572; called by muse, mutect2, varscan2
- SLC28A1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.26); catalogued as COSV54484617; called by muse, mutect2
- SLC38A4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56965157, COSV56970682; called by muse, mutect2, varscan2
- SLIT1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV56597326; called by muse, mutect2, varscan2
- SMARCA1 | c.2036C>G p.S679C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100946527; called by mutect2, varscan2
- SMC4 | c.3676G>C p.D1226H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59088316, COSV59088615; called by muse, mutect2, varscan2
- SMG5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV62437365; called by muse, mutect2, varscan2
- SNTB2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60351504; called by muse, mutect2, varscan2
- SNX33 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs765176187, COSV57914130; called by muse, mutect2, varscan2
- SPATS2L | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660383, COSV62352311; called by muse, mutect2, varscan2
- SPIRE2 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV65557389; called by muse, mutect2, varscan2
- SPNS2 | c.1342A>T p.M448L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61231455; called by muse, mutect2, varscan2
- SPRY1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59339156; called by muse, mutect2, varscan2
- SPSB1 | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV60164349; called by muse, mutect2, varscan2
- SPSB2 | c.660G>C p.R220S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV51290372; called by muse, mutect2, varscan2
- SPSB2 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369645281; called by mutect2, varscan2
- ST6GALNAC1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs151127625; called by muse, mutect2, varscan2
- ST8SIA5 | c.410G>C p.S137T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | PolyPhen possibly damaging (0.848); catalogued as rs1244960702, COSV59334533; called by muse, mutect2, varscan2
- SULF2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV63419488; called by muse, mutect2, varscan2
- SULT2B1 | c.315G>C p.E105D (on ENST00000201586 / NM_177973.2; = p.E90D on NM_004605.2) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV52378356; called by muse, mutect2, varscan2
- SYT13 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs141892837; called by muse, mutect2, varscan2
- TADA2B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1232633836, COSV59508394; called by muse, mutect2
- TET3 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV59882392; called by muse, mutect2, varscan2
- TG | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as COSV55091239, COSV99603914; called by muse, mutect2, varscan2
- TG | c.4212G>C p.Q1404H | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV55091251; called by muse, mutect2, varscan2
- TLR1 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV58305415, COSV58305857; called by muse, mutect2, varscan2
- TLR3 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as rs771080193, COSV57170098; called by mutect2, varscan2
- TLR9 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV62348199; called by muse, mutect2, varscan2
- TMEM121 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV66796633; called by muse, mutect2, varscan2
- TMEM131 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV51778446, COSV51784453; called by muse, mutect2, varscan2
- TMEM209 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as COSV61023468; called by muse, mutect2, varscan2
- TMEM30B | c.172A>G p.N58D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.291); catalogued as COSV63133981; called by muse, mutect2, varscan2
- TMEM63B | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.401); catalogued as COSV52481986; called by muse, mutect2, varscan2
- TMOD1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs767885123, COSV52251823; called by muse, mutect2, varscan2
- TMSB4X | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV66081937; called by muse, mutect2, varscan2
- TOMM22 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV53266147; called by muse, mutect2, varscan2
- TPH1 | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV51459983; called by muse, mutect2, varscan2
- TRIB3 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53932431; called by muse, mutect2, varscan2
- TRIM28 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV53399799; called by muse, mutect2, varscan2
- TRIM33 | c.3363G>C p.E1121D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61825377; called by muse, mutect2, varscan2
- TRPV4 | c.2572C>T p.Q858* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs144477274; called by muse, mutect2, varscan2
- TSPAN15 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV64783954; called by muse, mutect2, varscan2
- TSPYL1 | c.824T>A p.I275N | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63994270; called by muse, mutect2, varscan2
- TSPYL6 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57819265; called by muse, mutect2, varscan2
- TSSC4 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs778122292, COSV50180614; called by muse, mutect2, varscan2
- TTBK2 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV51175107; called by muse, mutect2, varscan2
- UAP1 | c.1504G>A p.E502K (on ENST00000271469 / NM_001324116.1; = p.E485K on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54850500, COSV54853127; called by muse, mutect2, varscan2
- UEVLD | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs564664426, COSV55579339; called by mutect2, varscan2
- UGT2B11 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1157439248, COSV71424204; called by muse, mutect2, varscan2
- UNC13D | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.772); catalogued as COSV52886881; called by muse, mutect2, varscan2
- USP7 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV61217024; called by muse, mutect2, varscan2
- VCAM1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV54121476; called by muse, mutect2, varscan2
- VILL | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.088); catalogued as COSV52187529; called by muse, mutect2, varscan2
- VTCN1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV60225122, COSV60225368; called by muse, mutect2, varscan2
- VWC2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61490657; called by muse, mutect2, varscan2
- WIZ | c.4196G>A p.R1399Q (on ENST00000673675 / NM_001371589.1; = p.R304Q on NM_021241.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as rs1372364515, COSV54606326; called by muse, mutect2, varscan2
- YARS1 | c.1455G>C p.K485N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV65114977; called by muse, mutect2, varscan2
- YIPF7 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs767571444, COSV60657980; called by muse, mutect2, varscan2
- ZBTB38 | c.3257G>C p.R1086T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV100375539, COSV58543875; called by muse, mutect2
- ZFAND2B | c.203G>T p.R68I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54699417; called by muse, mutect2, varscan2
- ZFP36L2 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as rs1558428791, COSV99143748; called by muse, mutect2, varscan2
- ZFX | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1462909993, COSV58449592; called by muse, mutect2, varscan2
- ZMAT1 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV65659814; called by muse, mutect2, varscan2
- ZMYM6 | c.2366T>G p.L789W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64122347; called by muse, mutect2, varscan2
- ZMYND10 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV51603773; called by muse, mutect2, varscan2
- ZNF281 | c.2497C>G p.Q833E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54169390; called by muse, mutect2
- ZNF420 | c.1836G>C p.E612D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58495929; called by muse, mutect2, varscan2
- ZNF467 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.033); catalogued as COSV57374573; called by muse, mutect2, varscan2
- ZNF76 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs762018098, COSV57354785; called by muse, mutect2, varscan2
- ZNF774 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62980837; called by muse, mutect2, varscan2
- ZNF780B | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV55467591; called by muse, varscan2
- ZNF804B | c.166del p.Y56Tfs*30 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as COSV60828768; called by mutect2, pindel, varscan2
- ZNRF1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.885); catalogued as COSV57729665; called by muse, mutect2, varscan2
- ZZEF1 | c.7859G>A p.R2620H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs903124457, COSV67559814; called by muse, mutect2, varscan2
- ACACA | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CTDNEP1 | c.654_657dup p.M220Pfs*11 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- HDAC9 | c.836_839dup p.N280Kfs*10 | Frame Shift Ins (INS) | VAF 42/149 reads (28%) | called by mutect2, varscan2
- IGHV4-28 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.231); called by muse, varscan2
- SUPT20HL1 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TBC1D3B | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ADGRA1 | c.1011G>A p.A337= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs759908171, COSV66924834, COSV66926828; called by muse, mutect2, varscan2
- ADGRG2 | c.849A>G p.P283= (on ENST00000379869 / NM_001079858.3; = p.P280= on NM_005756.4) | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs759261620, COSV61340894; called by mutect2, varscan2
- AFAP1L2 | c.1236C>T p.L412= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV58418050; called by muse, mutect2, varscan2
- ALPK3 | c.2625G>C p.L875= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51937126, COSV51938823; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1470C>T p.L490= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV51855463, COSV51856550; called by muse, mutect2, varscan2
- ARRDC3 | c.1077G>C p.R359= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV54366374; called by muse, mutect2, varscan2
- ARSH | c.1485G>A p.L495= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1367727579, COSV66963748, COSV66963796; called by muse, mutect2, varscan2
- ASAP3 | c.1926G>A p.L642= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV60877483; called by muse, mutect2, varscan2
- ASL | c.288G>A p.L96= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV59189230; called by muse, mutect2, varscan2
- ASPHD1 | c.825G>T p.L275= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58102909; called by muse, mutect2, varscan2
- ATP8B2 | c.2541C>T p.D847= (on ENST00000672630; = p.D814= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs747813653, COSV59248324; called by muse, mutect2, varscan2
- B4GALNT2 | c.786G>C p.R262= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV55927924; called by muse, mutect2, varscan2
- BEST3 | c.2006G>A p.*669= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs758767382, COSV58304774; called by muse, mutect2, varscan2
- BPIFB4 | c.1215G>A p.P405= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs200333820, COSV64952159; called by muse, mutect2, varscan2
- BRD9 | c.1368C>T p.L456= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs759766501, COSV100057215; called by muse, mutect2, varscan2
- CA12 | c.915C>T p.I305= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV51607670; called by muse, mutect2, varscan2
- CASD1 | c.960C>T p.F320= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV51974910; called by muse, mutect2, varscan2
- CC2D2A | c.219G>A p.L73= (on ENST00000424120 / NM_001378615.1; = p.E109K on NM_020785.2) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV67505356; called by muse, mutect2, varscan2
- CDH12 | c.2199C>T p.Y733= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs746650644, COSV66424640; called by muse, mutect2, varscan2
- CDH3 | c.2286G>A p.L762= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV99868319; called by muse, varscan2
- CFAP46 | c.8124G>A p.Q2708= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV54158403; called by muse, mutect2, varscan2
- CKAP4 | c.1491C>A p.P497= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV65173165; called by muse, mutect2, varscan2
- CKB | c.120G>A p.A40= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1475506841, COSV62379697; called by muse, mutect2, varscan2
- COL4A1 | c.2295T>C p.V765= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs192750030, COSV65430882; called by muse, mutect2, varscan2
- DDX50 | c.2202G>T p.R734= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV65293201; called by muse, mutect2, varscan2
- DMXL2 | c.5358C>T p.F1786= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV51854341; called by muse, mutect2, varscan2
- DNAH1 | c.7224C>T p.F2408= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV70234824; called by muse, mutect2, varscan2
- DNAH9 | c.7137C>T p.I2379= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV52372116; called by muse, mutect2, varscan2
- DNMT3A | c.1401C>T p.V467= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV53073393; called by muse, mutect2, varscan2
- DNTTIP1 | c.294G>A p.L98= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54784179, COSV54784704; called by muse, mutect2, varscan2
- DVL2 | c.696C>T p.L232= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV50039060; called by muse, varscan2
- DVL2 | c.594C>A p.L198= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV50039110; called by muse, mutect2, varscan2
- EGFR | c.1143C>T p.F381= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as rs1337319875, COSV51838068, COSV51860516; called by muse, mutect2, varscan2
- EHHADH | c.198C>T p.F66= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- EMC3 | c.645C>T p.N215= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1398058443, COSV55279558; called by muse, mutect2, varscan2
- EOGT | c.477C>T p.L159= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55153355; called by muse, mutect2, varscan2
- EPS8L1 | c.1122G>A p.L374= (on ENST00000201647 / NM_133180.3; = p.L247= on NM_017729.3) | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV52385496; called by muse, mutect2, varscan2
- F5 | c.4353C>A p.L1451= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV63127515; called by muse, mutect2, varscan2
- FAM114A1 | c.843C>T p.L281= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV62674564; called by mutect2, varscan2
- FAM114A2 | c.1452C>G p.L484= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61078615; called by muse, mutect2, varscan2
- FAM120C | c.1521C>T p.P507= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1557130151, COSV60262006; called by muse, mutect2, varscan2
- FAM50A | c.270G>A p.K90= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1557199749, COSV50132847; called by muse, mutect2, varscan2
- FAM86B1 | c.507C>T p.L169= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as rs1381092685, COSV100392244; called by muse, mutect2, varscan2
- FBXO24 | c.1134C>T p.I378= (on ENST00000241071 / NM_033506.3; = p.I416= on NM_012172.5) | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV53828945; called by muse, mutect2, varscan2
- FDXACB1 | c.741G>A p.E247= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52790613; called by muse, mutect2
- FER1L6 | c.1479G>A p.R493= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1416699856, COSV67552322; called by muse, varscan2
- G6PC | c.585C>T p.F195= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV53832384; called by muse, mutect2, varscan2
- GART | c.2124G>A p.R708= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1398709521, COSV67819501; called by muse, mutect2, varscan2
- GPT | c.192C>T p.I64= | Silent (SNP) | VAF 50/79 reads (63%) | catalogued as COSV52954564; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2592G>A p.L864= (on ENST00000265755 / NM_016328.3; = p.L849= on NM_005685.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1309172406, COSV99734701; called by muse, mutect2, varscan2
- HAUS4 | c.237G>A p.L79= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52828081; called by muse, mutect2, varscan2
- HERC1 | c.2487G>T p.L829= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV71249823; called by muse, mutect2, varscan2
- HOXA3 | c.30G>C p.S10= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV57828479; called by muse, mutect2, varscan2
- IFI16 | c.1134G>C p.L378= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV55534507, COSV55539248; called by muse, mutect2
- INTS6L | c.658T>C p.L220= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as COSV66085977; called by muse, mutect2, varscan2
- KATNB1 | c.1083C>G p.P361= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV65552822; called by muse, mutect2, varscan2
- KATNIP | c.4014C>G p.V1338= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV55189993; called by muse, mutect2, varscan2
- KCNA1 | c.246C>T p.F82= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV66837658; called by muse, mutect2, varscan2
- KIF21B | c.687C>T p.F229= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV59764515; called by muse, mutect2, varscan2
- LIF | c.567G>A p.G189= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1409628494, COSV50776686; called by muse, mutect2, varscan2
- LILRA2 | c.460C>T p.L154= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as COSV52196135; called by muse, mutect2, varscan2
- LPL | c.1278C>T p.F426= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs771051928, COSV60932579; called by muse, mutect2, varscan2
- LRPPRC | c.1812G>A p.L604= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53242351, COSV53244147; called by muse, varscan2
- LRRC71 | c.762C>G p.L254= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs770895934, COSV61656709; called by muse, mutect2, varscan2
- MAPK7 | c.819C>G p.L273= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV55191597; called by muse, mutect2, varscan2
- MCC | c.1731G>A p.K577= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56734710; called by muse, mutect2, varscan2
- MCC | c.822G>T p.R274= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV56734724; called by muse, mutect2, varscan2
- MCOLN1 | c.1488C>T p.L496= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV51179879; called by muse, varscan2
- MCOLN1 | c.1548C>G p.L516= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV51179934; called by muse, varscan2
- MED16 | c.1936C>T p.L646= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs761913910, COSV54126382; called by muse, mutect2, varscan2
- MFSD2B | c.1470C>T p.S490= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV57856020; called by muse, mutect2, varscan2
- MMP16 | c.1314T>G p.G438= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV54184924; called by muse, mutect2
- MORC1 | c.567G>C p.V189= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV51728939; called by muse, mutect2, varscan2
- MROH6 | c.1506C>T p.V502= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs754090618, COSV101295809; called by muse, varscan2
- MYO1B | c.717G>A p.S239= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as rs761999972, COSV58435569; called by muse, mutect2, varscan2
- MYO9A | c.5691G>A p.L1897= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs754729280, COSV61856433; called by mutect2, varscan2
- NAV1 | c.1350G>A p.R450= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99818824; called by muse, mutect2, varscan2
- NCKAP5 | c.219G>A p.L73= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV58469952; called by muse, mutect2, varscan2
- NEDD1 | c.768C>T p.F256= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57146325; called by muse, mutect2, varscan2
- NLRC3 | c.1089C>G p.L363= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57094970; called by muse, mutect2, varscan2
- NRDE2 | c.2907G>A p.L969= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV62964474; called by muse, mutect2, varscan2
- NRDE2 | c.2697C>T p.S899= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs772905104, COSV62964480; called by muse, mutect2, varscan2
- NSD1 | c.3654G>A p.L1218= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV61783174; called by muse, mutect2, varscan2
- NTF3 | c.102C>T p.L34= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1271106018, COSV58417307, COSV58418271; called by muse, mutect2, varscan2
- NUDT7 | c.24G>A p.E8= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs766420627, COSV51746927; called by muse, mutect2, varscan2
- OR10A6 | c.219C>T p.F73= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV59165857; called by muse, mutect2, varscan2
- OR10H5 | c.204C>T p.I68= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV100454711, COSV58277970; called by muse, mutect2
- OR2G2 | c.723C>T p.F241= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs765219287, COSV60740172; called by muse, mutect2, varscan2
- OR2L8 | c.186G>C p.L62= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV61725789, COSV61728082; called by muse, mutect2, varscan2
- OR2T1 | c.102C>T p.F34= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100822350, COSV63542727; called by muse, mutect2, varscan2
- ORC1 | c.1704C>G p.V568= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV65365002; called by muse, mutect2, varscan2
- PAK5 | c.753G>A p.A251= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs780571800, COSV62035905; called by mutect2, varscan2
- PARK7 | c.276G>A p.L92= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58580544; called by muse, mutect2
- PCDH17 | c.765C>T p.N255= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV64973411; called by muse, mutect2, varscan2
- PCDHGA7 | c.2070G>A p.T690= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs996601457, COSV53959331, COSV99538206; called by muse, mutect2, varscan2
- PIBF1 | c.1953G>A p.E651= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV58327409; called by muse, mutect2, varscan2
- POLR1A | c.3927G>A p.Q1309= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV55698504; called by muse, mutect2, varscan2
- POLR1A | c.3846G>A p.K1282= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55698515; called by muse, mutect2, varscan2
- PON3 | c.357C>T p.F119= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV55699907; called by muse, varscan2
- POU2F2 | c.732C>T p.F244= (on ENST00000526816 / NM_001207025.3; = p.F228= on NM_002698.5) | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs756460030, COSV60759957; called by mutect2, varscan2
- PPARG | c.1083G>A p.L361= (on ENST00000287820 / NM_015869.5; = p.L331= on NM_005037.7) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV55144947; called by muse, mutect2, varscan2
- PRKCZ | c.111C>T p.F37= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs573507359; called by muse, mutect2, varscan2
- PSTPIP1 | c.1203G>A p.R401= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs372384486; called by muse, mutect2, varscan2
- PTCD1 | c.1401G>A p.L467= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs920095829, COSV52865238, COSV99463806; called by muse, mutect2
- PTER | c.60G>A p.L20= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV54347144; called by muse, mutect2, varscan2
- PTPRN2 | c.2871G>A p.L957= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs144485708; called by muse, mutect2, varscan2
- RASA2 | c.1254G>A p.L418= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs771537926, COSV53945375; called by muse, mutect2, varscan2
- REXO4 | c.954G>A p.L318= | Silent (SNP) | VAF 65/79 reads (82%) | catalogued as rs1464169844, COSV64241156, COSV64241657; called by muse, mutect2, varscan2
- RHBDL2 | c.540C>G p.L180= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56709618; called by muse, mutect2
- RRM2 | c.243C>T p.V81= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58817697; called by muse, mutect2, varscan2
- RYR1 | c.5577G>A p.V1859= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV62108293; called by muse, mutect2, varscan2
- RYR2 | c.12378G>A p.L4126= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV63708589; called by muse, mutect2, varscan2
- SEC61A2 | c.450G>T p.L150= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100036419; called by mutect2, varscan2
- SFMBT2 | c.1932G>A p.L644= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1332920963, COSV62815364; called by muse, mutect2, varscan2
- SH3RF2 | c.585C>G p.L195= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV63040973; called by muse, mutect2, varscan2
- SIGIRR | c.420C>T p.V140= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1039115731, COSV100230021, COSV58985909; called by muse, mutect2, varscan2
- SLAIN1 | c.855C>T p.L285= (on ENST00000466548; = p.L22= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs376535190; called by muse, mutect2, varscan2
- SLC20A2 | c.1776C>A p.V592= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV60606421; called by muse, mutect2, varscan2
- SLC38A1 | c.1200C>G p.L400= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV67064739; called by muse, mutect2, varscan2
- SLC5A6 | c.1395C>G p.V465= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV60161043; called by muse, mutect2, varscan2
- SMURF1 | c.1485C>T p.I495= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV62816678; called by muse, mutect2, varscan2
- SORBS1 | c.1101G>A p.V367= (on ENST00000361941 / NM_001034954.2; = p.V203= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV53364118; called by muse, mutect2, varscan2
- SOX3 | c.453C>T p.R151= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV65167941; called by muse, mutect2, varscan2
- SPHK2 | c.1953G>A p.G651= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs750680338, COSV55341386; called by mutect2, varscan2
- STAT2 | c.828G>A p.L276= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV58477023; called by muse, varscan2
- STK10 | c.132C>T p.D44= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV51578099; called by muse, mutect2, varscan2
- STRC | c.4764C>T p.F1588= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs772901207, COSV55853497; called by muse, mutect2, varscan2
- SUCO | c.2874C>T p.I958= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs554267635, COSV55270204; called by muse, mutect2, varscan2
- TAF5 | c.1419C>T p.L473= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV60856149, COSV60857838; called by muse, mutect2, varscan2
- TBC1D10C | c.564C>G p.L188= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56704813; called by muse, mutect2, varscan2
- TGFB1I1 | c.1299C>T p.F433= (on ENST00000394863 / NM_001042454.3; = p.F416= on NM_015927.4) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV62359051; called by muse, mutect2, varscan2
- TGM2 | c.1521C>G p.L507= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100821668, COSV63932272; called by muse, mutect2
- TICRR | c.3723C>T p.L1241= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV51545944; called by muse, varscan2
- TICRR | c.3816C>T p.L1272= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV51545953; called by muse, mutect2
- TMCO3 | c.297C>T p.F99= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV64806895; called by muse, mutect2, varscan2
- TMED4 | c.60C>T p.L20= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV56942485; called by muse, mutect2, varscan2
- TMEM185A | c.996G>A p.Q332= | Silent (SNP) | VAF 28/575 reads (5%) | called by muse, mutect2
- TMEM63C | c.1500C>T p.F500= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV53607743; called by muse, mutect2, varscan2
- TNS3 | c.3933C>T p.C1311= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV60797455; called by muse, mutect2, varscan2
- TPCN1 | c.1107C>T p.F369= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs200616879, COSV100136692; called by muse, mutect2, varscan2
- TPST2 | c.501C>A p.V167= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV58681684; called by muse, mutect2, varscan2
- TSFM | c.924G>A p.P308= (on ENST00000323833 / NM_001172696.2; = p.P287= on NM_005726.6) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs775672491, COSV57683475; called by muse, mutect2, varscan2
- TSHR | c.291C>T p.F97= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53318929; called by muse, mutect2, varscan2
- TSPAN14 | c.195C>T p.V65= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV59369645; called by muse, mutect2, varscan2
- TTI1 | c.420G>A p.L140= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV65063071; called by muse, mutect2
- TTN | c.52449C>G p.V17483= (on ENST00000591111; = p.V10059= on NM_003319.4) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60289647; called by muse, mutect2, varscan2
- TTN | c.42942C>T p.D14314= (on ENST00000591111; = p.D6890= on NM_003319.4) | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs773495187, COSV100612173; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.42843C>T p.T14281= (on ENST00000591111; = p.T6857= on NM_003319.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs757006832, COSV60289677; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TYK2 | c.2028C>T p.V676= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs563722782, COSV53391284; called by muse, mutect2, varscan2
- UBL7 | c.81G>A p.E27= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100795396; called by muse, mutect2
- UGT2B11 | c.561G>A p.L187= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV71424202; called by muse, mutect2, varscan2
- VPS51 | c.1863C>T p.T621= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs756939246, COSV54207591, COSV99659834; called by muse, mutect2, varscan2
- YTHDC2 | c.3027C>G p.L1009= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV50738774, COSV50751254; called by muse, mutect2, varscan2
- ZNF470 | c.993G>A p.Q331= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV57970424; called by muse, mutect2, varscan2
- ZNF507 | c.63G>A p.L21= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs368961693; called by mutect2, varscan2
- ZNF839 | c.1347G>T p.R449= (on ENST00000558850 / NM_001267827.1; = p.R565= on NM_018335.5) | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV99216232; called by muse, mutect2, varscan2
- ZNRF4 | c.346C>T p.L116= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs766048748, COSV55776052, COSV99706721; called by muse, mutect2, varscan2
- ZZEF1 | c.4968C>G p.V1656= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101067794; called by mutect2, varscan2
- AC116366.2 | c.-638+10965G>C | Intron (SNP) | VAF 15/69 reads (22%) | catalogued as COSV61819780; called by muse, mutect2, varscan2
- AL109984.1 | n.186+4903C>T | Intron (SNP) | VAF 17/118 reads (14%) | catalogued as rs773608495, COSV63752254; called by muse, mutect2, varscan2
- C7orf65 | n.299G>A | RNA (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- CA6 | c.259+1997C>A | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV101077296, COSV66262833; called by muse, mutect2, varscan2
- CAST | c.-94C>T | 5'UTR (SNP) | VAF 10/49 reads (20%) | catalogued as rs140456913, COSV100352396; called by mutect2, varscan2
- CEP295 | chr11:93731033 G>A | 3'Flank (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- CR1 | c.487+12085G>C | Intron (SNP) | VAF 24/126 reads (19%) | catalogued as rs774262384, COSV65462294; called by muse, mutect2, varscan2
- FGF13 | c.50-127375C>T | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- NBPF7 | n.714G>A | RNA (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- PINK1 | c.*1T>A | 3'UTR (SNP) | VAF 25/36 reads (69%) | catalogued as COSV100387294; called by muse, mutect2, varscan2
- PKD2L2 | c.*18-2252G>C | Intron (SNP) | VAF 11/21 reads (52%) | catalogued as COSV50372256; called by muse, mutect2, varscan2
- SUGP1 | c.539-66G>C | Intron (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99895049; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-755C>A | 5'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- TRPM1 | c.724+1026C>T | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs757047033, COSV56640840; called by muse, mutect2, varscan2
- UGT2B11 | c.-1G>C | 5'UTR (SNP) | VAF 31/87 reads (36%) | catalogued as COSV71424211; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095610 C>G | 5'Flank (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56232459; called by muse, mutect2, varscan2
